Somatic mutation profile of tumor specimen TCGA-N9-A4PZ-01A (aliquot TCGA-N9-A4PZ-01A-22D-A28R-08) from TCGA case TCGA-N9-A4PZ, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Uterus, NOS; FIGO stage: Stage IIIC2; Age at diagnosis: 77.2 years (28,211 days).
Specimen TCGA-N9-A4PZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 81309039-5b38-4667-bdc1-8bd87327a0f5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-N9-A4PZ-11A (Solid Tissue Normal), aliquot TCGA-N9-A4PZ-11A-11D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3c6c63a5-4a12-41ea-9b85-c2885389341a

The open-access MAF lists 50 somatic variants for this specimen: 39 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 10, Nonsense Mutation 4, Splice Site 1, Frame Shift Ins 1, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.344G>T p.R115L | Missense Mutation (SNP) | VAF 26/63 reads (41%) | hotspot (GDC flag); SIFT tolerated (0.44); PolyPhen benign (0.177); catalogued as rs200018596, CM1312620, COSV55890007, COSV55898949, COSV55991501; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 36/42 reads (86%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA7 | c.1099C>T p.R367W | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.586); catalogued as rs779804502, COSV54032645; called by muse, mutect2, varscan2
- ATP4A | c.1750G>C p.V584L | Missense Mutation (SNP) | VAF 45/201 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.069); catalogued as rs1392141891; called by muse, mutect2, varscan2
- C16orf90 | c.469C>T p.Q157* (on ENST00000399645 / NM_001353385.2; = p.Q148* on NM_001080524.2) | Nonsense Mutation (SNP) | VAF 6/20 reads (30%) | catalogued as rs1374610011, COSV101290973; called by muse, mutect2, varscan2
- CRB1 | c.4005+1G>T p.X1335_splice | Splice Site (SNP) | VAF 10/220 reads (5%) | catalogued as CS040833; called by muse, mutect2
- DMRT3 | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as rs752829841, COSV51904535; called by muse, mutect2, varscan2
- FIG4 | c.1141C>G p.R381G | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as CM115116, COSV100020042; called by muse, mutect2, varscan2
- GALNT2 | c.1589A>C p.K530T | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.534); catalogued as rs1186054078; called by muse, mutect2, varscan2
- LRRC36 | c.781T>C p.S261P | Missense Mutation (SNP) | VAF 6/115 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs908440237, COSV99339064; called by muse, mutect2
- MAGEB2 | c.4C>T p.P2S | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs763345977, COSV66781576; called by muse, mutect2, varscan2
- MGAM | c.2197C>T p.R733* | Nonsense Mutation (SNP) | VAF 56/266 reads (21%) | catalogued as rs782352514; called by muse, mutect2, varscan2
- MTUS2 | c.1478G>A p.R493H | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs753146187, COSV70922099; called by muse, mutect2, varscan2
- NPY | c.110G>A p.G37D | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV54215880; called by muse, mutect2, varscan2
- NTRK1 | c.1024C>T p.R342W | Missense Mutation (SNP) | VAF 27/45 reads (60%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.663); catalogued as rs375878564; called by muse, mutect2, varscan2
- PKHD1L1 | c.6806G>C p.R2269P | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs762177904, COSV65747256; called by muse, mutect2, varscan2
- PPP1R3A | c.2764G>A p.E922K | Missense Mutation (SNP) | VAF 43/118 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs868268486, COSV52879587; called by muse, mutect2, varscan2
- ROBO2 | c.1040G>A p.W347* | Nonsense Mutation (SNP) | VAF 29/219 reads (13%) | catalogued as COSV59948647; called by muse, mutect2, varscan2
- SLC9C2 | c.1610G>T p.R537L | Missense Mutation (SNP) | VAF 26/171 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs745902865, COSV62947207; called by muse, mutect2, varscan2
- SYCP2 | c.797A>G p.N266S | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1190570357; called by muse, mutect2, varscan2
- TIMELESS | c.2219C>G p.A740G | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.163); catalogued as COSV57510163; called by muse, mutect2, varscan2
- TTC30B | c.1460A>G p.K487R | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.071); catalogued as rs752111529; called by muse, mutect2, varscan2
- ZFYVE16 | c.2050G>A p.V684I | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs774708139, COSV62015824; called by muse, mutect2, varscan2
- ADIPOR1 | c.417G>A p.W139* | Nonsense Mutation (SNP) | VAF 36/187 reads (19%) | called by muse, mutect2, varscan2
- C5orf38 | c.307G>T p.A103S | Missense Mutation (SNP) | VAF 60/129 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- CASR | c.2413A>C p.K805Q (on ENST00000490131; = p.K882Q on NM_000388.4) | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- INPP5F | c.3025T>A p.S1009T | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- IQGAP1 | c.53G>A p.G18D | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); called by muse, mutect2
- OR51T1 | c.230T>C p.I77T | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- PITPNM2 | c.436G>T p.D146Y | Missense Mutation (SNP) | VAF 63/120 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRODH2 | c.1124G>T p.G375V (on ENST00000301175; = p.G299V on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 85/317 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RNF151 | c.353G>T p.C118F | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- SSTR5 | c.212T>C p.M71T | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- TMX4 | c.734A>G p.E245G | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TTN | c.72045dup p.K24016* (on ENST00000591111; = p.K16592* on NM_003319.4) | Frame Shift Ins (INS) | VAF 106/214 reads (50%) | called by mutect2, pindel, varscan2
- URGCP | c.1044T>G p.F348L (on ENST00000453200 / NM_001077663.3; = p.F339L on NM_017920.4) | Missense Mutation (SNP) | VAF 49/117 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- WNK1 | c.3768_3782del p.R1256_V1260del (on ENST00000315939 / NM_018979.4; = p.R1009_V1013del on NM_014823.3) | In Frame Del (DEL) | VAF 10/98 reads (10%) | called by mutect2, pindel
- ZFP90 | c.878A>G p.H293R | Missense Mutation (SNP) | VAF 55/86 reads (64%) | SIFT tolerated (0.52); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- ZNF711 | c.1907A>T p.K636M | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ARHGEF18 | c.1065C>T p.L355= (on ENST00000359920 / NM_001130955.2; = p.L251= on NM_015318.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/29 reads (55%) | called by muse, mutect2, varscan2
- ARSK | c.21G>C p.S7= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as rs1476789382; called by muse, mutect2
- ILKAP | c.96C>T p.L32= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as rs748250985; called by muse, mutect2, varscan2
- KIRREL3 | c.1575C>T p.A525= | Silent (SNP) | VAF 34/39 reads (87%) | catalogued as rs778771356; called by muse, mutect2, varscan2
- KLHL34 | c.1419C>T p.R473= | Silent (SNP) | VAF 14/23 reads (61%) | called by muse, mutect2, varscan2
- MYO1F | c.1416C>T p.G472= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as rs770980207; called by muse, mutect2, varscan2
- NSD3 | c.1770C>A p.S590= | Silent (SNP) | VAF 23/63 reads (37%) | called by muse, mutect2, varscan2
- PCDHGA7 | c.2271C>G p.V757= | Silent (SNP) | VAF 92/128 reads (72%) | called by muse, mutect2, varscan2
- ZNF267 | c.2121G>T p.R707= | Silent (SNP) | VAF 26/45 reads (58%) | catalogued as COSV56252637; called by muse, mutect2, varscan2
- ZNF750 | c.1869G>A p.A623= | Silent (SNP) | VAF 17/77 reads (22%) | catalogued as rs1223059446; called by muse, mutect2, varscan2
- TPRN | c.2073+11G>A | Intron (SNP) | VAF 56/117 reads (48%) | catalogued as rs1377599996; called by muse, mutect2, varscan2
